TCGA case TCGA-13-A5FT — Ovarian Serous Cystadenocarcinoma (TCGA-OV)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Ovary; Tissue source site: Memorial Sloan Kettering. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/f3618472-32dc-4c90-a407-90050f68be85

Demographics
Sex at birth: female; Race: black or african american; Country of residence at enrollment: United States; Age at index: 67 years; Vital status: Alive.

Diagnoses (1)
1. Serous cystadenocarcinoma, NOS: ICD-O-3 morphology code: 8441/3; ICD-10 code: C56.9; Tissue or organ of origin: Ovary; Site of resection or biopsy: Ovary; Laterality: Bilateral; Classification of tumor: primary; Age at diagnosis: 67.7 years (24,743 days); Year of diagnosis: 2009; Method of diagnosis: Surgical Resection; FIGO stage: Stage IIIC; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: RX; Days to last follow up: 2,143 days (5.9 years).
   Pathology details: Consistent pathology review: Yes; Residual tumor measurement: No macroscopic disease.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Days to treatment start: 48 days; Days to treatment end: 117 days; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin; Days to treatment start: 49 days; Days to treatment end: 111 days; Treatment outcome: Complete Response.
   Recorded as not given: adjuvant Radiation Therapy, NOS.

Follow-up (4 entries)
- Days to follow up: 1,296 days (3.5 years); Disease response: Tumor Free.
- Days to follow up: 1,666 days (4.6 years); Disease response: Tumor Free.
- Days to follow up: 2,143 days (5.9 years); Disease response: Tumor Free.
- Karnofsky performance status: 70; Timepoint: Prior to Adjuvant Therapy.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-13-A5FT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT; Initial weight: 230 mg.
  Slide TCGA-13-A5FT-01A-01-TSA: Section location: Top; Percent tumor cells: 92; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 8; Percent stromal cells: 0; Percent lymphocyte infiltration: 1; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-13-A5FT-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-13-A5FT-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Serous Cystadenocarcinoma; Prospective collection: No; Retrospective collection: Yes; Tumor status: Tumor free; History neoadjuvant treatment: No; Performance status timing: Pre-Adjuvant Therapy; Method initial path diagnosis: Tumor resection; Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: No.
- Follow-up form 1: Lost to follow-up: No; Treatment outcome at TCGA followup: Complete Remission/Response; Tumor status: Tumor free; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 2,143 days; disease-specific survival: no event (censored), 2,143 days; disease-free interval: no event (censored), 2,143 days; progression-free interval: no event (censored), 2,143 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-13-A5FT-01A-11D-A402-01): tumor purity 0.85, ploidy 1.91, whole-genome doublings 0.
